Somatic mutation profile of tumor specimen MMRF_1706_1_BM_CD138pos (aliquot MMRF_1706_1_BM_CD138pos_T2_KBS5U_L05374) from MMRF case MMRF_1706, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.6 years (24,341 days).
Specimen MMRF_1706_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f53e4b8f-cd88-45cd-a003-e3fab0d23ddb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1706_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1706_1_PB_Whole_C3_KBS5U_L05360; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fc27ca5-4a36-4a4f-a381-61ac9064f856

The open-access MAF lists 188 somatic variants for this specimen: 63 protein-altering or splice-affecting, 29 silent, 96 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 55, Missense Mutation 53, Silent 29, Intron 23, 5'Flank 9, Frame Shift Del 5, 5'UTR 4, Nonsense Mutation 4, RNA 3, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEU1 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 70/310 reads (23%) | catalogued as rs104893984, CM013414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANKRD30A | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); catalogued as COSV64617301; called by muse, mutect2, varscan2
- DIDO1 | c.4175A>G p.D1392G | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56625589; called by muse, mutect2, varscan2
- EBF3 | c.889G>A p.G297R (on ENST00000355311 / NM_001375392.1; = p.G288R on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62478455; called by muse, mutect2, varscan2
- GIGYF1 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs758231819, COSV51945115; called by muse, mutect2, varscan2
- HNF1A | c.1583C>A p.T528N | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as CM064302; called by muse, mutect2, varscan2
- MYO10 | c.5617C>A p.P1873T | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs754376677, COSV57021832, COSV99945818; called by muse, mutect2, varscan2
- POLR1G | c.873G>C p.K291N | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs774856339; called by muse, mutect2, varscan2
- RYR2 | c.13652C>T p.S4551F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63666654; called by muse, mutect2
- SLC22A2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.426); catalogued as rs762880984; called by muse, mutect2, varscan2
- SWT1 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV62255570; called by muse, mutect2, varscan2
- SYNRG | c.1081A>G p.M361V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1043308472; called by muse, mutect2
- UNC80 | c.9496G>A p.V3166M | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.036); catalogued as rs931962251; called by muse, mutect2
- ZNF696 | c.262del p.R88Efs*273 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | catalogued as COSV100350675; called by mutect2, varscan2
- ABCC12 | c.3721A>G p.K1241E | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ADGRG4 | c.1897G>C p.A633P | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- AK7 | c.1019T>G p.I340S | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AMOTL1 | c.2791C>A p.P931T | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.014); called by muse, mutect2
- C1QTNF4 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLIP4 | c.1770G>C p.E590D | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- CNTNAP5 | c.2779C>A p.L927I | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.371); called by muse, mutect2
- COL17A1 | c.2440T>G p.S814A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL1 | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- EEF1A1 | c.293_294del p.F98Yfs*12 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | called by mutect2, varscan2
- EIF4G1 | c.2374del p.E792Nfs*34 (on ENST00000346169 / NM_198241.3; = p.E597Nfs*34 on NM_004953.5) | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- ELAVL3 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 112/229 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FAT1 | c.1853A>C p.N618T | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- FAT3 | c.12835G>A p.G4279S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2
- FEM1C | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- FER1L5 | c.1657A>G p.N553D (on ENST00000623019; = p.N558D on NM_001293083.2) | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- H2BC4 | c.290C>G p.T97R | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- HLX | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPD | c.593T>G p.I198R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- HPS5 | c.1774G>C p.E592Q (on ENST00000349215 / NM_181507.2; = p.E478Q on NM_007216.4) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- INTS2 | c.3197T>C p.I1066T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- ITGB4 | c.4358G>T p.G1453V | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- KRTAP10-1 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- LILRB2 | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2
- MAML3 | c.1849A>G p.T617A | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); called by muse, mutect2
- MON1B | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- MYH4 | c.5008G>A p.D1670N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2
- NINL | c.3236G>C p.R1079T | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NUP133 | c.2087T>C p.V696A | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- OGT | c.62_71del p.F21* | Frame Shift Del (DEL) | VAF 77/169 reads (46%) | called by mutect2, pindel, varscan2
- OR14A2 | c.906G>T p.L302F | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR2AG2 | c.838A>C p.I280L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.367); called by muse, mutect2
- OR4C6 | c.847T>A p.L283M | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2
- PARN | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLOD2 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 13/322 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- POU4F2 | c.373A>C p.S125R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.423); called by muse, mutect2
- PRKAG1 | c.168+2T>A p.X56_splice | Splice Site (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- PRKN | c.782T>A p.L261* | Nonsense Mutation (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- RASAL2 | c.767G>T p.S256I | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RESF1 | c.3925A>T p.K1309* | Nonsense Mutation (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- RUVBL2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SETD5 | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- STARD13 | c.3161A>G p.Y1054C (on ENST00000336934 / NM_001243476.3; = p.Y936C on NM_052851.3) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SYNM | c.4577T>C p.F1526S (on ENST00000336292 / NM_145728.3; = p.F1214S on NM_015286.6) | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TGFBR2 | c.194A>T p.K65I | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.079); called by muse, varscan2
- TKTL2 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); called by muse, mutect2
- TUBGCP6 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ZDHHC17 | c.1005del p.Y335* | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- ASXL1 | c.628C>T p.L210= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- BCAS4 | c.42C>T p.N14= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV52811693; called by muse, mutect2
- C1orf226 | c.771C>A p.S257= | Silent (SNP) | VAF 64/208 reads (31%) | called by muse, mutect2, varscan2
- CALHM4 | c.276C>A p.I92= | Silent (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- CFAP54 | c.5928T>G p.G1976= | Silent (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- CHST8 | c.1128G>A p.R376= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV52863982; called by muse, mutect2
- DNAJC10 | c.822G>A p.Q274= | Silent (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- DNHD1 | c.9813C>T p.A3271= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- DOP1B | c.3594G>A p.A1198= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as rs747344855; called by muse, mutect2
- ERAP1 | c.1890A>T p.A630= | Silent (SNP) | VAF 62/228 reads (27%) | called by muse, mutect2, varscan2
- FAM120A | c.1602G>A p.S534= | Silent (SNP) | VAF 50/203 reads (25%) | catalogued as rs780691067, COSV52905363; called by muse, mutect2, varscan2
- FGG | c.936T>C p.A312= | Silent (SNP) | VAF 43/168 reads (26%) | called by muse, mutect2, varscan2
- GPR27 | c.279G>A p.L93= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV55204466; called by muse, mutect2
- HLX | c.1395T>A p.P465= | Silent (SNP) | VAF 42/169 reads (25%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.102A>C p.T34= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs559222113; called by muse, varscan2
- IL31RA | c.276T>C p.A92= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- INSYN1 | c.168G>A p.Q56= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV65837379; called by muse, mutect2, varscan2
- LRP5 | c.1704C>T p.I568= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs200627198; called by muse, mutect2, varscan2
- MEFV | c.2103G>A p.A701= | Silent (SNP) | VAF 19/309 reads (6%) | catalogued as rs104895095, COSV54818684; ClinVar: benign / not provided; called by muse, mutect2
- MGAT5B | c.138G>A p.S46= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1289165130; called by muse, mutect2
- NTAQ1 | c.522C>T p.N174= | Silent (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- PCDH11Y | c.1614C>T p.G538= (on ENST00000400457 / NM_032973.2; = p.G527= on NM_032971.3) | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2
- RAF1 | c.48A>T p.G16= | Silent (SNP) | VAF 16/261 reads (6%) | called by muse, mutect2
- RFTN1 | c.726A>T p.G242= | Silent (SNP) | VAF 72/163 reads (44%) | called by muse, varscan2
- SIGLEC9 | c.1425C>T p.L475= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- ST6GAL2 | c.1407C>T p.H469= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs1313384342; called by muse, mutect2, varscan2
- TRIM13 | c.1113C>T p.Y371= | Silent (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- TSPYL2 | c.591G>A p.Q197= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- ZSCAN4 | c.264C>T p.V88= | Silent (SNP) | VAF 12/274 reads (4%) | catalogued as COSV58998867; called by muse, mutect2
- ABRAXAS1 | c.179-2246T>C | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- AC005324.2 | c.*1860C>T | 3'UTR (SNP) | VAF 19/346 reads (5%) | catalogued as rs922025912; called by muse, mutect2
- AK2 | c.*4178A>G | 3'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- ALPP | chr2:232378743 T>C | 5'Flank (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500273 A>C | 5'Flank (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- ARPC5L | c.*362A>G | 3'UTR (SNP) | VAF 4/90 reads (4%) | catalogued as rs1433047757; called by muse, mutect2
- BCL7A | chr12:122021300 G>C | 5'Flank (SNP) | VAF 28/115 reads (24%) | called by muse, varscan2
- BCL7A | chr12:122021387 del CAGGCGACGT | 5'Flank (DEL) | VAF 14/88 reads (16%) | called by pindel, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 16/93 reads (17%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, varscan2
- BTBD1 | c.*235dup | 3'UTR (INS) | VAF 20/110 reads (18%) | catalogued as rs1426365958; called by mutect2, varscan2
- C12orf75 | c.*244G>A | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- CA5A | chr16:87936545 C>T | 5'Flank (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- CAPN8 | c.1136-1139_1136-1138insA | Intron (INS) | VAF 23/42 reads (55%) | called by mutect2, varscan2*
- CASZ1 | c.*1779A>C | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- CCDC103 | chr17:44902945 A>C | 3'Flank (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- CCNI2 | c.*354C>T | 3'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- CEP97 | c.*527C>G | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- CHEK1 | c.*27+52T>C | Intron (SNP) | VAF 12/238 reads (5%) | catalogued as rs952890763; called by muse, mutect2
- CUL3 | c.*2988T>A | 3'UTR (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- CUL9 | c.3850-49T>A | Intron (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- CYP1A1 | c.*316A>G | 3'UTR (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- FOXL2NB | c.*849T>G | 3'UTR (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- FOXQ1 | c.*323G>A | 3'UTR (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- FYB1 | c.*1486C>G | 3'UTR (SNP) | VAF 5/103 reads (5%) | called by muse, mutect2
- GABRA1 | c.*208G>A | 3'UTR (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2
- GALNT8 | chr12:4851030 G>T | 3'Flank (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- GRIK1 | c.1251+147T>C | Intron (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- HDAC11 | c.*1368G>A | 3'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- HHIP | c.*5194C>T | 3'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- HMCN1 | c.*780T>C | 3'UTR (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.*1179A>C | 3'UTR (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- IGFBP3 | c.751-58C>T | Intron (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- ISY1 | c.*192T>A | 3'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- KDM2B | c.126+505G>A | Intron (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- KDR | c.2615-54T>C | Intron (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- LAMC3 | c.*1053C>A | 3'UTR (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- LHFPL4 | c.*252C>T | 3'UTR (SNP) | VAF 16/45 reads (36%) | catalogued as rs1453661329; called by muse, mutect2, varscan2
- LONRF2 | c.*6892G>T | 3'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- LRRC15 | c.*333C>A | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- LTB | c.163-41G>C | Intron (SNP) | VAF 18/395 reads (5%) | catalogued as rs4647183, COSV53001370; called by muse, mutect2
- MACROH2A1 | c.953+36T>G | Intron (SNP) | VAF 57/117 reads (49%) | called by muse, mutect2, varscan2
- MEOX2 | c.*127G>T | 3'UTR (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- MRPL52 | c.-28C>T | 5'UTR (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- MSRB3 | c.*182A>T | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12799T>G | Intron (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- NCAM2 | c.*3486C>A | 3'UTR (SNP) | VAF 9/34 reads (26%) | called by muse, varscan2
- NEMP1 | c.*2535C>G | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- NKAIN2 | c.474+496T>C | Intron (SNP) | VAF 37/107 reads (35%) | catalogued as rs1351581421, COSV63641901; called by muse, varscan2
- NOC2LP2 | n.1550A>T | RNA (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- NPTXR | c.*2278G>A | 3'UTR (SNP) | VAF 26/74 reads (35%) | catalogued as rs751960080; called by muse, mutect2, varscan2
- NPTXR | c.*194G>A | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- ONECUT2 | c.*7568C>T | 3'UTR (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*11603T>A | 3'UTR (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- OR2C3 | c.*4606A>G | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- PATZ1 | c.1272-98A>C | Intron (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2
- PAX5 | c.*3044C>T | 3'UTR (SNP) | VAF 48/150 reads (32%) | catalogued as rs569556304; called by muse, mutect2, varscan2
- PDCD6IP | c.-72T>G | 5'UTR (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- PHF20 | c.*2630C>T | 3'UTR (SNP) | VAF 33/74 reads (45%) | catalogued as rs868809474; called by muse, mutect2, varscan2
- PI15 | c.*2614A>T | 3'UTR (SNP) | VAF 20/69 reads (29%) | catalogued as rs897396684; called by muse, mutect2, varscan2
- PLCB2 | c.582+1025A>G | Intron (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
- PRDM13 | c.*691G>T | 3'UTR (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- PREX2 | c.*5261del | 3'UTR (DEL) | VAF 20/54 reads (37%) | called by mutect2, varscan2
- PTGER3 | c.1077+3637A>T | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2
- PTPRK | c.2492-1404G>T | Intron (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- ROR1 | c.*1557del | 3'UTR (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- SAV1 | c.*137G>T | 3'UTR (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- SEMA3D | c.*686A>G | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- SEMA5A | c.*3850T>G | 3'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- SFT2D2 | c.-74C>A | 5'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2
- SLC3A2 | chr11:62855085 G>A | 5'Flank (SNP) | VAF 44/126 reads (35%) | catalogued as rs748220538; called by muse, mutect2, varscan2
- SLC44A1 | c.*3168A>T | 3'UTR (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2
- SMOC2 | c.*1049A>C | 3'UTR (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- SNORD116-19 | n.88G>A | RNA (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- SPTLC2 | c.*6231T>G | 3'UTR (SNP) | VAF 5/110 reads (5%) | called by muse, mutect2
- SSPOP | n.14628C>A | RNA (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- SYT15 | c.*1070C>T | 3'UTR (SNP) | VAF 10/74 reads (14%) | catalogued as rs1262748690, COSV100970797; called by muse, mutect2
- TBC1D1 | c.*1252G>A | 3'UTR (SNP) | VAF 18/76 reads (24%) | called by muse, varscan2
- THBS2 | c.*1691C>T | 3'UTR (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- TMEM19 | c.*2671T>G | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- TMEM52B | c.*136C>G | 3'UTR (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- TMSB4X | chrX:12975293 T>G | 5'Flank (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+49G>A | Intron (SNP) | VAF 33/63 reads (52%) | catalogued as rs1467208758; called by muse, mutect2, varscan2
- TRA2B | c.*950T>C | 3'UTR (SNP) | VAF 29/145 reads (20%) | called by muse, mutect2, varscan2
- TSPAN19 | c.594+53T>A | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2
- TTLL10 | c.1401+658C>T | Intron (SNP) | VAF 30/74 reads (41%) | catalogued as rs530942679; called by muse, mutect2, varscan2
- TTYH3 | c.*1076C>T | 3'UTR (SNP) | VAF 12/129 reads (9%) | catalogued as rs551872744; called by muse, mutect2
- TUBA1C | c.-69G>A | 5'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- UBC | c.-4+208T>A | Intron (SNP) | VAF 48/180 reads (27%) | called by muse, varscan2
- UBC | c.-4+130dup | Intron (INS) | VAF 26/163 reads (16%) | called by pindel, varscan2
- UBXN2B | c.*3781T>G | 3'UTR (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- VNN1 | c.*1592A>G | 3'UTR (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- WDR41 | chr5:77492356 C>A | 5'Flank (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- YY1 | c.*3888T>G | 3'UTR (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- ZMYND11 | c.117-11935C>A | Intron (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- ZNF536 | c.*130C>A | 3'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2
- ZSCAN25 | c.590-65A>G | Intron (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
